Surgical pathology report (de-identified scan), TCGA case TCGA-36-2547, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2547-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

TCGA – 36 – 2547

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Specimen labelled LEFT OVARY showing:

1. High-grade serous carcinoma of left ovary.
2. Ovarian surface involvement present.
3. Tumour identified within lumen and partially replacing the epithelial lining of left fallopian tube.

B. Specimen labelled BLADDER PERITONEUM showing metastatic high-grade serous carcinoma.

C. Uterus, right ovary and tubes (total hysterectomy with right salpingo-oophorectomy):

1. Serous carcinoma involving uterine serosa.
2. Right fallopian tube serosa involved by tumour.
3. Unremarkable right ovary, negative for malignancy.
4. Leiomyoma.
5. Unremarkable cervix, negative for malignancy.

D. Omentum showing fibrofatty tissue extensively replaced by high-grade serous carcinoma.

E. Peritoneal washing: Positive for malignant cells.

[page 2 of 3]
[REDACTED]

Clinical History as Provided by Submitting Physician:

[REDACTED]

- A. Left ovary
- B. Bladder peritoneum
- C. Cervix, uterus, ovary
- D. Omentum

Specimens Received:

- A: left ovary
- B: bladder peritoneum
- C: cervix, uterus + ovary
- D: omentum

Gross Description:

The specimen is received in four containers each labelled with the patient's demographics.

Container A is labelled LEFT OVARY and consists of an intact cystically enlarged ovary measuring 10 x 8.5 x 5 cm, weighing 303 gm. The external surface shows area of papillary growth measuring 1.7 cm in greatest dimension that is inked black. Elsewhere the external surface shows smooth serosa. The fallopian tube measures 3.5 cm in length, 0.4 cm in diameter. Cross section of the ovary shows unilocular cyst filled with straw-colored fluid. The inner lining of the cyst shows papillary tumor measuring 6.5 cm in greatest dimension that on cross section shows tan-white fibrous structure with areas of punctate hemorrhage. It is grossly coming to the inked surface.

Representative sections are submitted as follows:

- A1, A2-tumor and external surface
- A3-A7-ovary
- A8-A9-fallopian tube

Container B is labelled BLADDER PERITONEUM and consists of fragment of fibrous tissues measuring 1.4 x 0.9 x 0.3 cm. The specimen submitted in toto as B1.

[page 3 of 3]
Container C is labelled CERVIX, UTERUS, OVARIES and consists of a uterus with right adnexa weighing in toto 71 gm. The uterus measures 7.5 x 4.5 x 2.5 cm. The fallopian tube measures 7 cm in length x 0.9 cm in diameter. The ovary measures 3 cm x 1.2 x 0.5 cm. The serosal surface of the specimen shows diffuse papillary growth that is inked black. The cervix measures 3.5 cm in length, 2.7 cm in diameter. The mucosa of the endocervix is normal.

The bi-valved uterus shows unremarkable endocervical canal. The endometrium is even with a thickness of 0.1 cm. Cross of the anterior myometrium shows one apparently fibroid nodule measuring 1.6 cm in diameter but on cross section shows grayish fibroid without hemorrhage or irregularities. Elsewhere the myometrium is symmetrical with a maximum thickness of 1.6 cm. Cross section of the right ovary shows unremarkable structure.

Representative sections are submitted as follows:

C1,C2-cervix anterior/posterior cervix
C3 -cul-de-sac
C4,C5-isthmus, anterior/posterior
C6,C7-myometrium, anterior/posterior

Cross section of the fimbrial end of the fallopian tube shows tan-white fibrous nodule measuring 1.2 cm in greatest dimension.

C8-C10-right adnexa

Container D is labelled OMENTUM and consists of an apron of great omentum measuring 26 x 14 x 4 cm that is distorted by numerous fibrous nodules ranging in size from 0.8 up to 11 x 6 cm.

Representative sections are submitted as D1 through D3

Copies to

Source: NCI Genomic Data Commons file 73606f20-f47e-4884-bc7e-31a7d7364848 (TCGA-36-2547.F615F400-96C3-42F3-BEE9-C273B1A16B63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).